Gene-level copy-number profile of specimen HCM-CSHL-0076-C25-85A from HCMI case HCM-CSHL-0076-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 74.8 years (27,308 days).
Specimen HCM-CSHL-0076-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 49ab401a-d522-44b4-9c33-7cb436e925fd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0076-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/547732f1-8adc-4859-9b6f-7196315ec75c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 72; copy number 1: 10,232; copy number 2: 46,000; copy number 3: 2,090; copy number 4: 6; copy number 6: 5.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–23,956,444, 72 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:22,409,237–22,618,868, 2 genes, copy number 6 (within-gene range 1–6): AC053513.1, C2CD5.
- chr12:22,573,425–22,625,015, 3 genes, copy number 6: LRRC34P1, AC087241.1, AC087241.2.

Autosomal genes at a single copy (total copy number 1): 10,232. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
